CCDI case PBCBXF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/3edfed48-a518-4014-8720-6f7976e6edba

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Gastrointestinal stromal tumor, NOS: ICD-O-3 morphology code: 8936/1; Tissue or organ of origin: Gastrointestinal tract, NOS; Age at diagnosis: 16.2 years (5,914 days).

Biospecimens (3 samples)
- Sample 0DNWJI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNWJQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNWLN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
